Gene-level copy-number profile of tumor specimen TCGA-CN-6995-01A from TCGA case TCGA-CN-6995, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 79.0 years (28,850 days).
Specimen TCGA-CN-6995-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.1adaa8c2-7fb7-4dd6-b65b-edc4dfca909e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CN-6995-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2567a206-af50-4e14-8adf-708f0163a42f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 10,617; copy number 3: 16,624; copy number 4: 24,058; copy number 5: 3,204; copy number 6: 2,835; copy number 7: 900; copy number 8: 240; copy number 9: 239; copy number 10: 772; copy number 11: 233; copy number 14: 4; copy number 16: 36; copy number 23: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CN-6995-01A-31D-2010-01): tumor purity 0.37, ploidy 3.7, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,339 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:145,523,538–198,222,513, 933 genes, copy number 10–11 (broad region; genes not listed).
- chr8:42,752,620–43,674,591, 36 genes, copy number 16: CHRNA6, THAP1, AC087533.1, RNF170, RN7SL806P, MIR4469, HOOK3, Y_RNA, AC110275.1, FNTA, RNU1-124P, POMK, AC113191.1, HGSNAT, VN1R46P, AC022616.5, AC022616.7, AC022616.3, AC022616.2, AFG3L2P1, AC022616.1, AC022616.4, POTEA, RNU6-104P, AC022616.8, AC022616.6, U3, AC134698.1, AC134698.4, AC134698.3, SNX18P27, AC134698.5, CYP4F44P, AC134698.2, AC139365.2, AC139365.1.
- chr8:119,557,086–135,299,719, 239 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr11:68,460,731–72,434,680, 131 genes, copy number 10–23 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
